TCGA case TCGA-CR-6472 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Base of tongue; Tissue source site: Vanderbilt University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0956bc67-dd55-4c54-a56a-f22f2856662a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C01; Tissue or organ of origin: Base of tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 59.3 years (21,654 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N3; AJCC clinical M: M0; AJCC clinical stage: Stage IVB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Induction; Days to treatment start: 28 days; Days to treatment end: 84 days; Number of cycles: 9; Prescribed dose: 2; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Induction; Days to treatment start: 28 days; Days to treatment end: 84 days; Number of cycles: 9; Prescribed dose: 60; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 109 days; Days to treatment end: 123 days; Number of cycles: 3; Prescribed dose: 1; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 109 days; Days to treatment end: 123 days; Number of cycles: 3; Prescribed dose: 30; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 109 days; Days to treatment end: 154 days; Treatment dose: 6,930 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 109 days; Days to treatment end: 154 days; Treatment dose: 5,610 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 109 days; Days to treatment end: 154 days; Treatment dose: 6,930 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Cure; Days to treatment end: 154 days; Treatment outcome: No Measurable Disease; Chemo concurrent to radiation: Yes.
2. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Thyroid gland; Laterality: Left; Classification of tumor: Synchronous primary.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 384 days (1.1 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 1,050 days (2.9 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.
- Alcohol history: No; Alcohol drinks per day: 0; Alcohol days per week: 0.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CR-6472-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
  Slide TCGA-CR-6472-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-CR-6472-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph node neck dissection indicator: No; Tobacco smoking history indicator: 1; Alcohol history documented: Yes; Alcohol consumption frequency: 0.
- Drug treatment 1: Regimen number: 2; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Primary: Concurrent.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Primary: Induction.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tobacco smokeless use at diagnosis: No; Tobacco smokeless regular use: No; Definitive treatment method: Concurrent Chemotherapy; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Thyroid Papillary Carcinoma - Classical/usual.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: 270.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous malignancy of thyroid cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,050 days; disease-specific survival: no event (censored), 1,050 days; progression-free interval: no event (censored), 1,050 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CR-6472-01A-11D-1869-01): tumor purity 0.75, ploidy 1.78, whole-genome doublings 0.
